Somatic mutation profile of tumor specimen BA2720D (aliquot aq-BA2720D) from BEATAML1.0 case 2394, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 23.8 years (8,695 days).
Specimen BA2720D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a69fa0e9-d406-4b59-a134-0193f34cd8c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2264D (Solid Tissue Normal), aliquot aq-BA2264D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d579091-eed4-4ef1-ad07-982f33baff2c

The open-access MAF lists 150 somatic variants for this specimen: 101 protein-altering or splice-affecting, 34 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 34, Nonsense Mutation 8, Intron 7, Splice Site 5, Splice Region 4, Frame Shift Del 3, 5'Flank 3, RNA 2, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS10 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs758296848; called by muse, mutect2, varscan2
- BBS10 | c.1351A>T p.S451C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV67913263; called by muse, mutect2, varscan2
- CDHR1 | c.1547C>A p.A516E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV60565785; called by muse, mutect2, varscan2
- CORO6 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs766020064; called by muse, mutect2
- DPYSL4 | c.68G>T p.R23M | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV100634002; called by muse, mutect2, varscan2
- DTWD1 | c.275A>T p.K92M | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370934143; called by muse, mutect2, varscan2
- EFTUD2 | c.2562G>A p.R854= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as rs896547317; called by mutect2, varscan2
- GRIA4 | c.983C>G p.A328G | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as COSV99231396; called by muse, mutect2, varscan2
- IGSF5 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs148668253, COSV66030885; called by muse, mutect2
- KIF21A | c.1020-1G>T p.X340_splice | Splice Site (SNP) | VAF 33/260 reads (13%) | catalogued as COSV62769576; called by muse, mutect2, varscan2
- KRT24 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.069); catalogued as COSV52879892; called by muse, mutect2
- KRT26 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 26/397 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56971046; called by muse, mutect2
- MUC5B | c.15844C>T p.P5282S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs775832209; called by muse, varscan2
- NBEA | c.8599G>T p.A2867S | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs747475015, COSV100079258; called by muse, mutect2, varscan2
- NF1 | c.3975-2A>T p.X1325_splice | Splice Site (SNP) | VAF 13/253 reads (5%) | catalogued as CS971828, COSV62194646, COSV62198856; called by muse, mutect2
- OR12D3 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101011094; called by muse, mutect2
- OVGP1 | c.1870T>C p.S624P | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1356699485; called by muse, mutect2, varscan2
- RRM1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV100331219; called by muse, mutect2
- SP7 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58190731; called by muse, mutect2
- SPG7 | c.2038G>A p.G680R (on ENST00000268704; = p.G687R on NM_003119.4) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as rs767715658, COSV51948200; called by muse, mutect2, varscan2
- STK11 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881974, CM011964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THAP12 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99472875; called by muse, mutect2, varscan2
- TTN | c.10711G>A p.G3571R (on ENST00000591111; = p.G3525R on NM_003319.4) | Missense Mutation (SNP) | VAF 27/218 reads (12%) | catalogued as COSV60129025; called by muse, mutect2, varscan2
- TXNRD2 | c.591+5G>C | Splice Region (SNP) | VAF 22/138 reads (16%) | catalogued as rs947152207; called by mutect2, varscan2
- WT1 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 18/234 reads (8%) | catalogued as COSV100186554; called by muse, mutect2
- ZNF33B | c.715A>G p.R239G | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs1376049633; called by muse, mutect2
- ACAN | c.7672C>A p.H2558N (on ENST00000560601 / NM_001369268.1; = p.H2421N on NM_001135.3) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1583A>T p.E528V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ADAR | c.3403G>A p.D1135N | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); called by muse, mutect2
- AGRN | c.3332G>T p.G1111V | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALKBH8 | c.635T>A p.L212* | Nonsense Mutation (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2
- ANKS1B | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APCS | c.605_606del p.L202Rfs*8 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- ARHGAP21 | c.3559G>A p.G1187R | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF15 | c.1705-4C>T | Splice Region (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- ASTN1 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2
- C1orf167 | c.3376G>A p.A1126T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CFAP206 | c.1162del p.D388Ifs*3 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- CLIP4 | c.1547G>C p.G516A | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLTCL1 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- CREBRF | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.147); called by muse, mutect2
- CSNK1A1 | c.7A>T p.S3C | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYFIP1 | c.913del p.V305Ffs*9 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- CYP27B1 | c.549dup p.R184Sfs*149 | Frame Shift Ins (INS) | VAF 37/199 reads (19%) | called by mutect2, pindel, varscan2
- DOCK7 | c.4454A>T p.D1485V (on ENST00000635253 / NM_001367561.1; = p.D1454V on NM_033407.3) | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DOCK7 | c.4453G>C p.D1485H (on ENST00000635253 / NM_001367561.1; = p.D1454H on NM_033407.3) | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DPP4 | c.1682T>A p.L561Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DTWD2 | c.542G>A p.W181* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- EDN3 | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); called by muse, mutect2
- EML6 | c.2641G>A p.G881R | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXOC4 | c.87G>A p.R29= | Splice Region (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- EXOSC9 | c.341A>T p.K114M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FRYL | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- H1-8 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.153); called by muse, varscan2
- HERC1 | c.11495G>A p.C3832Y | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- HSD17B4 | c.696A>T p.E232D (on ENST00000414835 / NM_001199291.3; = p.E207D on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- IFNA10 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2
- IGHV3-30 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KCNA2 | c.271T>A p.Y91N | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KIF21A | c.1020-2A>T p.X340_splice | Splice Site (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- MTMR3 | c.3225+1G>T p.X1075_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- MTRR | c.1139-1G>A p.X380_splice (on ENST00000264668; = p.X353_splice on NM_002454.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 28/192 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.38068A>T p.S12690C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MYO9B | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NIN | c.5383G>T p.E1795* (on ENST00000382041 / NM_182946.1; = p.E1082* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- NLRX1 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.117); called by muse, mutect2
- NOS1 | c.1284G>T p.K428N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP205 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- OXSR1 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGS1 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2
- PITPNM3 | c.281T>A p.L94Q | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2
- PTPRQ | c.1438G>T p.E480* (on ENST00000616559; = p.E438* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- PTPRQ | c.1439A>T p.E480V (on ENST00000616559; = p.E438V on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- RBBP6 | c.3379G>T p.E1127* | Nonsense Mutation (SNP) | VAF 19/265 reads (7%) | called by muse, mutect2
- RC3H1 | c.997A>T p.S333C | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RDH10 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- RNF133 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF213 | c.4195G>A p.E1399K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- RP9 | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); called by muse, mutect2
- RYR2 | c.10073A>T p.E3358V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- SCML2 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SH2D7 | c.176A>T p.K59M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SIRT1 | c.1191G>T p.R397S | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2
- SLC35F6 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- STARD9 | c.5425A>T p.I1809F | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- SYCP2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- SYN1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAF8 | c.230A>T p.K77M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TENM4 | c.6794G>T p.G2265V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX15 | c.4822G>C p.A1608P (on ENST00000256246; = p.A1991P on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TG | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2
- TPBG | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- TSBP1 | c.592A>T p.M198L (on ENST00000617061; = p.M201L on NM_006781.5) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- TSPOAP1 | c.4485G>T p.L1495F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- UFL1 | c.1341A>T p.K447N | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- USP33 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- UTP6 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- VEGFC | c.214G>C p.V72L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- XYLT1 | c.1767G>T p.Q589H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ZNF254 | c.603A>T p.K201N | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- ZNF277 | c.159A>T p.E53D | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- ABL2 | c.2634G>A p.G878= (on ENST00000502732 / NM_007314.4; = p.G863= on NM_005158.5) | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- ALPL | c.1122G>T p.V374= | Silent (SNP) | VAF 34/230 reads (15%) | called by muse, mutect2, varscan2
- ANK2 | c.9417G>A p.R3139= | Silent (SNP) | VAF 32/362 reads (9%) | called by muse, mutect2
- ASTN2 | c.1734C>A p.A578= (on ENST00000313400 / NM_001365069.1; = p.A527= on NM_014010.5) | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- ATG2A | c.3387A>T p.P1129= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- ATP8B3 | c.2553G>A p.Q851= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CDC42BPA | c.3321A>T p.I1107= (on ENST00000334218 / NM_001366019.2; = p.I1094= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CEP128 | c.1692G>A p.E564= | Silent (SNP) | VAF 62/355 reads (17%) | catalogued as rs1208137937; called by muse, mutect2, varscan2
- CLEC12A | c.75C>T p.G25= | Silent (SNP) | VAF 39/375 reads (10%) | catalogued as COSV58560885; called by muse, mutect2
- CREB3L2 | c.831G>A p.E277= | Silent (SNP) | VAF 13/151 reads (9%) | called by muse, mutect2
- EDC4 | c.849T>C p.V283= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs1162988287; called by muse, mutect2, varscan2
- EDN3 | c.528T>A p.T176= | Silent (SNP) | VAF 24/344 reads (7%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.918G>A p.E306= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- FAHD1 | c.345G>A p.K115= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs768645041; called by muse, mutect2, varscan2
- GPATCH2 | c.537G>T p.R179= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100861335; called by muse, mutect2, varscan2
- MPPE1 | c.99G>C p.V33= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV100013283; called by muse, mutect2
- MUC16 | c.1044C>T p.S348= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as rs1379153220; called by muse, mutect2
- MYH1 | c.2013C>T p.P671= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV56843063; called by muse, mutect2, varscan2
- OR4K15 | c.415C>T p.L139= (on ENST00000305051; = p.L115= on NM_001005486.1) | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs1455668152; called by muse, mutect2
- OXER1 | c.1155C>T p.S385= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as COSV54309654; called by muse, mutect2
- PDE6A | c.1272T>A p.T424= | Silent (SNP) | VAF 18/291 reads (6%) | called by muse, mutect2
- PDZK1 | c.507T>C p.A169= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- PIWIL2 | c.2358C>T p.D786= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- PPP1R37 | c.2019G>A p.K673= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs911618081; called by muse, mutect2, varscan2
- RBM6 | c.2826G>A p.K942= | Silent (SNP) | VAF 13/197 reads (7%) | called by muse, mutect2
- RYR1 | c.12204G>A p.K4068= | Silent (SNP) | VAF 53/289 reads (18%) | catalogued as COSV62094632; called by muse, mutect2, varscan2
- SBSPON | c.30G>T p.A10= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs866552582; called by muse, mutect2
- SEH1L | c.414A>T p.I138= | Silent (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- SETBP1 | c.1809G>A p.E603= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV99955275; called by muse, mutect2
- SPRY2 | c.843G>T p.G281= | Silent (SNP) | VAF 16/461 reads (3%) | called by muse, mutect2
- TMEM121 | c.432G>A p.E144= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs1451313771; called by muse, mutect2, varscan2
- TMTC1 | c.1683G>A p.Q561= (on ENST00000539277 / NM_001193451.2; = p.Q453= on NM_175861.3) | Silent (SNP) | VAF 23/328 reads (7%) | called by muse, mutect2
- WT1 | c.948A>G p.L316= | Silent (SNP) | VAF 19/233 reads (8%) | catalogued as COSV60086970; called by muse, mutect2
- ZC3H3 | c.582G>A p.K194= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs1317604579; called by muse, mutect2, varscan2
- C19orf12 | chr19:29700703 C>T | 3'Flank (SNP) | VAF 14/123 reads (11%) | catalogued as rs1339762572, COSV60364119; called by muse, mutect2, varscan2
- CD8A | chr2:86791032 A>C | 5'Flank (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- COCH | c.-31T>C | 5'UTR (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- CTAGE1 | c.*862C>A | 3'UTR (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
- GFOD1 | c.253+16430A>T | Intron (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- KRT18P55 | n.587C>T | RNA (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- LETMD1 | chr12:51048270 A>T | 5'Flank (SNP) | VAF 14/199 reads (7%) | called by muse, mutect2
- LMBR1 | c.758-2257G>A | Intron (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85588A>G | Intron (SNP) | VAF 24/124 reads (19%) | called by mutect2, varscan2
- PIAS3 | c.804+70G>T | Intron (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- PPP3R1 | chr2:68261229 A>C | 5'Flank (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- RSPH1 | c.54+22G>A | Intron (SNP) | VAF 7/96 reads (7%) | catalogued as COSV99370673; called by muse, mutect2
- RUNX1 | c.724+122G>T | Intron (SNP) | VAF 45/225 reads (20%) | called by muse, mutect2, varscan2
- SNORD115-4 | n.36G>A | RNA (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- WDR1 | c.17-85A>T | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
